Gene-level copy-number profile of tumor specimen TCGA-2G-AAF4-01A from TCGA case TCGA-2G-AAF4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 30.1 years (10,983 days).
Specimen TCGA-2G-AAF4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.d4ac2166-ac65-4cff-aea9-6a49cd41cce5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAF4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/217b5f9f-4698-47d3-8e28-6f46e071b6f6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,291; copy number 2: 11,722; copy number 3: 13,733; copy number 4: 24,426; copy number 5: 6,832; copy number 6: 1,172; copy number 7: 105; copy number 9: 533.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAF4-01A-11D-A42X-01): tumor purity 0.42, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 533 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–178,455, 1 gene, copy number 9 (within-gene range 4–9): IQSEC3.
- chr12:137,411–15,903,478, 532 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,283. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
